Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NL, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NL-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

A year-old male recently diagnosed with distal esophageal cancer - adenocarcinoma with longstanding GERD and recent dysphagia. Patient underwent staging EUS at (no enlarged lymph nodes) at patient started to have increased abdominal pain. Right chest pain radiating to scapula - found to have free air below diaphragm, mediastinal air and air in neck soft tissues. No fever, diarrhea, or constipation, positive episodes of emesis. Possible esophageal perforation.

PROCEDURE:

VERIFIED BY:

1. "Stomach" Received in formalin in a medium container is a 6.2 cm long x 5.2 cm in internal circumference portion of distal esophagus with a 10.2 x 5.6 x 1.3 cm proximal cuff of stomach. The adventitia is pink-tan and roughened and is remarkable for a 1.3 x 0.5 cm perforation with a granular yellow-tan material extending from it. The perforation is 3.9 cm away from the proximal margin. The mucosa is grey-white and in the area of perforation it has a granular yellow-tan appearance measuring 1.5 x 0.7 cm. This is located at the esophageal gastric junction. Adjacent to the perforation is a 4.3 x 2.5 cm ulcerative tumor that is 3.6 away from the proximal margin and 2.3 cm away from the distal margin. The mid point of the tumor is located at the esophageal gastric junction. Upon sectioning through the esophageal gastric junction the tumor extends submucosally forming a somewhat annular ring except for at the area of perforation. Tumor has a maximum depth of 1.3 cm and extends to the adventitia.

1A.&B. Perforation.

1C. Tumor to adjacent proximal.

1D. Tumor to adjacent distal.

1E. Tumor to deep.

1F. Esophagogastric junction with tumor underlying mucosa.

1G. Stomach.

1H. Multiple lymph nodes.

2. "Cervical margin" Received in formalin in a small container is a 2.2 cm long x 1.5 cm in diameter portion of esophagus.

3. "Cervical lymph node" Received in formalin in a small container is a 1.9 cm possible lymph node.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

ICD-O-3

Adenocarcinoma NOS 8140/3
Site ^{path} Esophagus, distal third C16.5
Gastroesophageal junction C16.2
QW 1/17/14

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Type of carcinoma: Adenocarcinoma arising in GE junction, not otherwise specified.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 4/9

Extranodal metastasis: Unknown

Pattern of invasion: Infiltrative.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T3 N1 MX

PROCEDURE:

VERIFIED BY:

1-2. Esophagus and proximal stomach, transhiatal esophagectomy: Invasive adenocarcinoma arising at the esophagogastric junction. No Barrett's mucosa identified. The neoplasm penetrates through the muscularis propria and extends into the adventitia/subserosa. Fibrinopurulent exudate covers portions of the serosa consistent with the clinical history of perforation. Proximal and distal surgical margins negative. Four of eight regional lymph nodes are positive for metastatic carcinoma. Extracapsular extension of tumor is identified with one of the positive nodes. See template.

3. Cervical lymph node, excision: One lymph node negative for neoplasm.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Review	10/11/13	File
For Malignancy History		
See Is (circle):	DISCREPANCY	

Source: NCI Genomic Data Commons file 8f0c5518-cbc5-4983-bf61-7de564ca5029 (TCGA-L5-A8NL.1FCAF9C7-B16C-4C8A-A820-49C276FE1E6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).